Gene-level copy-number profile of tumor specimen TCGA-06-2559-01A from TCGA case TCGA-06-2559, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 83.7 years (30,580 days).
Specimen TCGA-06-2559-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.65148ff3-8e73-4ff2-8d64-10a272f84972.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-06-2559-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 352 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3bc412c9-b0e8-4075-ba1d-a553e7d4690e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 5,124; copy number 2: 51,823; copy number 3: 3,126; copy number 4: 4; copy number 5: 7; copy number 6: 25; copy number 7: 34; copy number 8: 10; copy number 9: 15; copy number 11: 1; copy number 19: 6; copy number 20: 25; copy number 22: 2; copy number 24: 6; copy number 25: 17; copy number 29: 32; copy number 32: 8; copy number 40: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-06-2559-01A-01D-0784-01): tumor purity 0.9, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:55,673,536–55,686,160, 3 genes (within-gene range 0–2): OR4V1P, OR4P1P, AP006437.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 191 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:51,843,000–56,710,614, 102 genes, copy number 6–40 (broad region; genes not listed).
- chr4:115,920,707–116,952,699, 16 genes, copy number 7: KRT18P21, AC027613.1, EIF3KP3, TTC39CP1, MTRNR2L13, MIR1973, TRMT112P1, CUL4AP1, AC106892.1, ACTN4P1, AC093765.5, AC093765.4, AC093765.3, AC093765.2, RNU6-119P, AC093765.1.
- chr4:117,249,924–117,412,712, 3 genes, copy number 7: AC107399.1, LINC02262, LINC02263.
- chr4:117,413,462–117,414,279, 1 gene, copy number 7: RPSAP35.
- chr4:117,834,145–118,258,634, 3 genes, copy number 7: LINC02264, NDST3, FKBP4P1.
- chr4:118,664,087–118,838,683, 3 genes, copy number 5 (within-gene range 3–5): METTL14-DT, METTL14, SEC24D.
- chr4:119,135,832–119,628,804, 15 genes, copy number 9: MYOZ2, AC092656.1, USP53, C4orf3, FABP2, KLHL2P1, RNU4-33P, AC110373.1, GTF2IP12, AC093752.3, RNU6-1217P, AC093752.1, AC093752.2, PDE5A, AC080089.1.
- chr4:119,799,089–120,066,858, 6 genes, copy number 7: LINC01365, AC097173.1, LINC02502, Y_RNA, AC097173.2, MAD2L1.
- chr4:120,091,046–120,092,282, 1 gene, copy number 7: LTV1P1.
- chr4:121,131,408–121,227,466, 2 genes, copy number 6 (within-gene range 3–6): TNIP3, RNU6-948P.
- chr4:122,378,966–122,456,725, 2 genes, copy number 7: ADAD1, IL2.
- chr6:106,695,535–107,051,586, 6 genes, copy number 5–7: LINC02526, LINC02532, RNU6-117P, MIR587, CD24, MTRES1.
- chr12:57,674,665–58,105,935, 31 genes, copy number 19–20: RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2.

Autosomal genes at a single copy (total copy number 1): 2,737. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
